Gene-level copy-number profile of specimen HCM-SANG-0308-C15-85A from HCMI case HCM-SANG-0308-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0308-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d55b43bb-021b-4093-87ca-57abbb1bdde5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0308-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,738 have no estimate.
https://portal.gdc.cancer.gov/files/208ff8ef-9e27-4f1a-acac-863db36aa1c1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 18; copy number 2: 4,147; copy number 3: 17,586; copy number 4: 19,826; copy number 5: 11,846; copy number 6: 1,677; copy number 7: 3,383; copy number 8: 86; copy number 9: 70; copy number 10: 108; copy number 11: 35; copy number 23: 17; copy number 24: 15; copy number 25: 3; copy number 28: 4; copy number 30: 1; copy number 34: 3; copy number 35: 1; copy number 38: 8.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:4,143,458–4,150,421, 1 gene: UNC93B4.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr18:5,721,812–8,406,861, 41 genes (within-gene range 0–7): MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1, AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2.
- chr18:15,056,845–15,066,598, 1 gene: AP005242.3.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–7): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 265 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,596,953–27,864,401, 52 genes, copy number 23–38: ABT1, AL513548.3, AL513548.2, ZNF322, AL513548.1, GUSBP2, POM121L6P, LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P, RNU2-62P, AL021807.1, H2BC11, H2AC11, H4C9, H2BC12, H2AC12, MIR3143, RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.3, AL021918.2, AL021918.1, HNRNPA1P1, CD83P1, RNU6-471P, RPL8P1, LINC01012, GPR89P, RSL24D1P1, H4C10P, H2BC13, H2AC13, H3C10, H2AC14, H2BC14, H4C11, H4C12, H2AC15, H2BC16P.
- chr6:27,937,465–28,369,172, 33 genes, copy number 9–11: OR2W6P, OR2B6, RPLP2P1, OR2W4P, IQCB2P, ZSCAN16-AS1, U3, OR2W2P, OR2B7P, OR2B8P, OR1F12, AL121944.1, ZNF165, ZSCAN12P1, ZNF602P, ZSCAN16, AL358933.1, ZKSCAN8, ZNF192P1, AL022393.1, ZNF603P, ZNF192P2, TOB2P1, ZSCAN9, ZKSCAN4, NKAPL, ZSCAN26, AL021997.2, PGBD1, AL021997.1, SMIM15P2, ZSCAN31, ZKSCAN3.
- chr6:28,410,270–30,989,903, 180 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
